Gene-level copy-number profile of tumor specimen TCGA-UB-A7ME-01A from TCGA case TCGA-UB-A7ME, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 51.6 years (18,846 days).
Specimen TCGA-UB-A7ME-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.c5faefe4-16fd-47c3-9e7c-acbc5b882107.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UB-A7ME-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c2794d60-effe-4de6-89e7-cb4510af7bad

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 532; copy number 2: 13,130; copy number 3: 21,241; copy number 4: 13,716; copy number 5: 1,314; copy number 6: 5,877; copy number 7: 3,582; copy number 8: 214; copy number 9: 105; copy number 11: 20; copy number 13: 42; copy number 14: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UB-A7ME-01A-11D-A33B-01): tumor purity 0.49, ploidy 3.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,003 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:17,444,010–40,504,563, 315 genes, copy number 7 (broad region; genes not listed).
- chr5:40,825,262–42,721,878, 23 genes, copy number 7 (within-gene range 5–7): RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1.
- chr5:105,922,994–106,546,803, 4 genes, copy number 8: RNA5SP189, AC027313.1, AC114940.1, AC114940.2.
- chr5:114,475,339–115,632,992, 22 genes, copy number 8 (within-gene range 3–8): AC010230.1, LINC01957, AC094104.2, AC094104.1, TRIM36, TRIM36-IT1, AC008494.2, PGGT1B, AC008494.3, AC008494.1, CCDC112, HMGN1P15, CTNNA1P1, AK3P4, AC008628.2, AC008628.1, CCT5P1, FEM1C, TICAM2, TMED7-TICAM2, AC010226.1, TMED7.
- chr6:60,281,444–84,227,643, 258 genes, copy number 7–9 (broad region; genes not listed).
- chr6:85,449,584–88,066,838, 55 genes, copy number 11–14 (within-gene range 6–14): NT5E, AL589666.2, SNX14, AL589666.1, SYNCRIP, SNHG5, PKMP3, SNORD50B, AL355615.1, SMIM11P1, RNU4-72P, Y_RNA, AL450338.1, AL450338.2, RNU4-12P, RPL7P27, RAB1AP2, NDUFA5P9, AL391417.1, RN7SL643P, AL353133.1, AL353133.2, AL157777.1, AL157777.2, HTR1E, RPL7P29, MTHFD2P2, AL138827.1, RN7SKP209, CGA, RCN1P1, AL139274.2, ZNF292, AL139274.1, GJB7, HSPD1P10, SMIM8, C6orf163, AL096817.1, CFAP206, AL049697.1, AL049697.2, AL049697.3, ST13P16, SLC35A1, RNU6-444P, RARS2, ORC3, AKIRIN2, AL133211.1, Y_RNA, RN7SL183P, AL590392.1, AL136096.1, SPACA1.
- chr6:95,917,143–96,521,717, 5 genes, copy number 14 (within-gene range 2–14): AL034348.1, KRT18P50, FUT9, UFL1-AS1, RN7SL797P.
- chr7:75,986,831–77,995,171, 58 genes, copy number 7: TMEM120A, STYXL1, AC006330.1, MDH2, AC005077.4, RNU6-863P, GTF2IP7, AC005077.2, AC005077.1, AC005077.3, SRRM3, HSPB1, YWHAG, PPIAP81, SSC4D, ZP3, DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16, AC004980.1, POMZP3, AC004980.2, AC006972.1, AC007003.1, DTX2P1-UPK3BP1-PMS2P11, FDPSP7, AC114737.1, DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17, PMS2P9, Y_RNA, AC007000.3, SPDYE18, AC007000.2, FAM185BP, AC007000.1, CCDC146, FGL2, AC098851.1, GSAP, AC004921.1, GCNT1P5, AC004921.2, PTPN12, APTR, RSBN1L, TMEM60, PHTF2, Y_RNA, AC004990.1.
- chr8:35,235,475–35,796,550, 1 gene, copy number 7 (within-gene range 2–7): UNC5D.
- chr8:35,525,176–36,191,194, 5 genes, copy number 7 (within-gene range 2–7): LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3.
- chr8:51,257,688–145,066,685, 1,457 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr10:38,762,095–43,981,102, 66 genes, copy number 7 (broad region; genes not listed).
- chr11:27,888,838–30,322,988, 29 genes, copy number 7 (within-gene range 4–7): HSP90AA2P, AC090159.1, KIF18A, MIR610, METTL15, ATP5MGP8, RN7SKP158, AC104978.1, MIR8068, AC013714.1, LINC02758, LINC02742, OR2BH1P, AC090791.1, AC110056.1, LINC02755, AC090124.2, AC090124.1, AC110058.1, LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4, AL358944.1, AL358944.2, FSHB.
- chr11:66,070,272–105,531,697, 885 genes, copy number 7–8 (broad region; genes not listed).
- chr11:106,051,098–109,583,907, 50 genes, copy number 8 (within-gene range 2–8): KBTBD3, AASDHPPT, AP001001.1, AP001001.2, LINC02719, AP002001.3, AP002001.1, AP002001.2, AP003173.1, GUCY1A2, AP001282.2, AP001282.1, ASS1P13, AP000766.1, CWF19L2, SMARCE1P1, ALKBH8, AP001823.1, ELMOD1, AP000889.2, AP000889.1, SLN, AP002353.1, SLC35F2, AP001024.1, RAB39A, AP003307.1, CUL5, Y_RNA, AP002433.1, ACAT1, AP002433.2, NPAT, ATM, Y_RNA, C11orf65, POGLUT3, EXPH5, DDX10, RPS2P39, AP002453.1, CYCSP29, AP003027.1, AP003123.1, RNU6-654P, RNA5SP349, SNORD39, AP003049.2, C11orf87, AP003049.1.
- chr11:128,934,731–132,404,060, 54 genes, copy number 7–13: TP53AIP1, ARHGAP32, RNU6-876P, Y_RNA, RNU6-874P, ZNF123P, BARX2, RPS27P20, AP003500.1, LINC01395, AP003327.2, AP003327.1, TMEM45B, NFRKB, PRDM10, LINC00167, AP003041.1, ELOBP2, AP003041.2, APLP2, RPL34P21, U4, ST14, ZBTB44, NDUFAF2P2, DDX18P5, RN7SL778P, ZBTB44-DT, ADAMTS8, ADAMTS15, AP004371.1, BAK1P2, MIR8052, LINC02873, AP003486.2, PPP1R10P1, LINC02551, SNX19, AP003486.1, RN7SL167P, AP002856.3, AP002856.1, AP002856.4, AP002856.2, NTM, RNU6ATAC12P, AP003025.1, AP003025.2, NTM-AS1, AP004372.1, AP000844.2, AP000844.1, NTM-IT, AP000843.1.
- chr11:132,525,809–132,773,371, 2 genes, copy number 13: U6, AP003784.1.
- chr14:18,333,726–38,041,442, 671 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr16:7,126,293–8,376,276, 10 genes, copy number 7: AC022206.1, AC007222.2, AC007222.1, AC005774.2, AC005774.1, AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1.
- chr18:72,536,680–75,074,205, 33 genes, copy number 8: CBLN2, HNRNPA1P11, NETO1, AC023301.1, RNA5SP460, MIR548AV, AC091138.1, LINC02864, LINC02582, AC079070.1, RN7SL401P, AC090125.1, AC010947.1, AC090125.2, FBXO15, TIMM21, AC090398.1, RN7SL551P, CYB5A, AC090398.2, C18orf63, FAUP1, LINC01922, DIPK1C, AC009704.3, CNDP2, AC009704.2, CNDP1, AC009704.1, LINC00909, ZNF407, AC015819.2, AC015819.1.

Autosomal genes at a single copy (total copy number 1): 532. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
